Somatic mutation profile of tumor specimen C3N-01525-03 (aliquot CPT0095890077) from CPTAC case C3N-01525, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.3 years (28,217 days).
Specimen C3N-01525-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 966c2468-8ba0-4423-b1f6-597372feca31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01525-31 (Blood Derived Normal), aliquot CPT0095910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c89a6daa-2a39-45b3-865a-0862dc6b2c48

The open-access MAF lists 106 somatic variants for this specimen: 77 protein-altering or splice-affecting, 19 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 19, Intron 7, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 2, In Frame Del 1, Splice Region 1, 3'UTR 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD4 | c.3341G>A p.R1114Q (on ENST00000357008 / NM_001363606.2; = p.R1127Q on NM_001273.5) | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs886039917, COSV58895679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 20/388 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 208/511 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4180G>A p.A1394T | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1173154389; called by muse, mutect2, varscan2
- ARHGEF10L | c.2032G>A p.G678S | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355345589; called by muse, mutect2, varscan2
- ARID3B | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs753085247; called by muse, mutect2, varscan2
- ATP2A1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767886671; called by muse, mutect2, varscan2
- BEX2 | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.966); catalogued as rs1471821591; called by muse, mutect2
- CACNA1E | c.4102G>A p.V1368I | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs574530214, COSV62402477; called by muse, mutect2, varscan2
- CAMTA1 | c.3553A>G p.S1185G | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs954409338; called by muse, mutect2, varscan2
- CLCN4 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as COSV101073820; called by muse, mutect2
- DLG5 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 137/282 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488016884, COSV64948531; called by muse, mutect2, varscan2
- EPHB6 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 169/807 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs201556658, COSV63892635; called by muse, mutect2, varscan2
- GRIA4 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs151104343; called by muse, mutect2, varscan2
- GRIK5 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs201959426; called by muse, mutect2, varscan2
- HEPACAM | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 115/461 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs751732183, COSV53430381; called by muse, mutect2, varscan2
- HRNR | c.8408G>A p.S2803N | Missense Mutation (SNP) | VAF 141/464 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as rs552697734; called by muse, mutect2, varscan2
- HSF4 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 177/560 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50456664; called by muse, mutect2, varscan2
- JAG1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 100/341 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as rs766370717; called by muse, mutect2, varscan2
- KANSL1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs376632173; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KIAA1109 | c.9572T>G p.L3191R | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52661427; called by muse, mutect2, varscan2
- KIAA2026 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 131/409 reads (32%) | catalogued as rs1228518521; called by muse, mutect2, varscan2
- L1CAM | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs1557093462; called by muse, mutect2
- LGI2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs139692298, COSV66123183; called by muse, mutect2, varscan2
- MAMLD1 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs1005490291; called by muse, mutect2, varscan2
- MAP1S | c.2587C>T p.R863W | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749473307; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- NICN1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748614806, COSV56469044, COSV56471088; called by muse, mutect2, varscan2
- NKTR | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 50/167 reads (30%) | catalogued as rs1479671676; called by muse, mutect2, varscan2
- NLRP4 | c.1496T>G p.L499W | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as rs907483906, COSV56708637, COSV56710687; called by muse, mutect2, varscan2
- NOS3 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 55/328 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.713); catalogued as rs767108240; called by muse, mutect2, varscan2
- NR5A1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs752292248, COSV65295683; called by muse, mutect2, varscan2
- OR10A7 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 99/370 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV58278864; called by muse, mutect2, varscan2
- OR8D1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs562758196, COSV63441771; called by muse, mutect2, varscan2
- PARP4 | c.2860T>C p.W954R | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1420177812; called by muse, mutect2, varscan2
- PAX1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68271303; called by muse, mutect2, varscan2
- PCDH1 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99745856; called by muse, mutect2, varscan2
- PCDHGB2 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 35/417 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs573308473, COSV53966534; called by muse, mutect2
- PIK3R1 | c.1685G>C p.R562P (on ENST00000521381 / NM_181523.3; = p.R292P on NM_181504.4) | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV57124822; called by muse, mutect2, varscan2
- PRMT8 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs747021868; called by muse, mutect2, varscan2
- ROPN1L | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1190893461; called by muse, mutect2, varscan2
- RYR1 | c.9560G>A p.R3187Q | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1171145743; called by muse, mutect2
- SLC16A13 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 23/367 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142971810, COSV57273738; called by muse, mutect2
- SRC | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1479989919; called by muse, mutect2, varscan2
- STARD6 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs145044397, COSV104410849; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 133/350 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs755371712, COSV51513640; called by muse, mutect2, varscan2
- ARID1A | c.5465del p.P1822Hfs*61 | Frame Shift Del (DEL) | VAF 51/169 reads (30%) | called by mutect2, pindel, varscan2
- ARID5B | c.1431_1434del p.L478* | Frame Shift Del (DEL) | VAF 27/58 reads (47%) | called by mutect2, pindel, varscan2
- ASH1L | c.3679T>A p.F1227I | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- B4GALT1 | c.1003G>T p.V335F | Missense Mutation (SNP) | VAF 94/323 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- C2orf68 | c.296_307del p.E99_S103delinsA | In Frame Del (DEL) | VAF 32/172 reads (19%) | called by mutect2, pindel, varscan2
- CHPF | c.2263G>A p.G755S | Missense Mutation (SNP) | VAF 120/267 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ERO1B | c.818A>G p.K273R | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FSIP2 | c.9247G>T p.V3083F | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLCE | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- HLA-DQA1 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- HNRNPH3 | c.58_61dup p.R21Pfs*68 | Frame Shift Ins (INS) | VAF 28/194 reads (14%) | called by mutect2, pindel, varscan2
- KCNA7 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 134/500 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- KCNH3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 96/351 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KMT2E | c.4373C>T p.T1458I | Missense Mutation (SNP) | VAF 83/444 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MX1 | c.1951_1952del p.T651Afs*20 | Frame Shift Del (DEL) | VAF 47/217 reads (22%) | called by mutect2, pindel, varscan2
- MYO10 | c.2464A>T p.K822* | Nonsense Mutation (SNP) | VAF 85/224 reads (38%) | called by muse, mutect2, varscan2
- NIPSNAP3A | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- PLSCR5 | c.315C>A p.S105R | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- RYR2 | c.4634C>A p.A1545E | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SBF2 | c.1860+7del | Splice Region (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel
- SLC25A51 | c.163del p.L55Sfs*18 | Frame Shift Del (DEL) | VAF 49/192 reads (26%) | called by mutect2, pindel, varscan2
- SLC4A10 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.354); called by muse, mutect2
- SLC6A19 | c.1277G>A p.C426Y | Missense Mutation (SNP) | VAF 120/447 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- STAT5A | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- VIM | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 111/447 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNK4 | c.1780T>C p.F594L | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2
- ZFP36L2 | c.548dup p.R184Afs*290 | Frame Shift Ins (INS) | VAF 320/944 reads (34%) | called by mutect2, pindel, varscan2
- ZIC3 | c.764G>A p.W255* | Nonsense Mutation (SNP) | VAF 76/301 reads (25%) | called by muse, mutect2, varscan2
- ZNF331 | c.1172_1178del p.A391Vfs*7 | Frame Shift Del (DEL) | VAF 46/180 reads (26%) | called by mutect2, pindel, varscan2
- ZNF624 | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ZNF865 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- BMP2 | c.264T>G p.G88= | Silent (SNP) | VAF 52/131 reads (40%) | called by muse, mutect2
- EPHA2 | c.1191G>T p.V397= | Silent (SNP) | VAF 129/472 reads (27%) | called by muse, mutect2, varscan2
- FRMPD3 | c.2607G>A p.P869= | Silent (SNP) | VAF 91/347 reads (26%) | catalogued as rs1451679884; called by muse, mutect2, varscan2
- GALNT3 | c.588A>G p.E196= | Silent (SNP) | VAF 51/241 reads (21%) | called by muse, mutect2, varscan2
- HDAC4 | c.882C>T p.S294= | Silent (SNP) | VAF 73/242 reads (30%) | catalogued as rs911608166, COSV100612898; called by muse, mutect2, varscan2
- ITPRID1 | c.1299G>A p.P433= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as rs1277567601; called by muse, mutect2, varscan2
- KLHL33 | c.255T>C p.P85= | Silent (SNP) | VAF 113/345 reads (33%) | called by muse, mutect2, varscan2
- MAP1A | c.3774C>T p.P1258= | Silent (SNP) | VAF 73/245 reads (30%) | called by muse, mutect2, varscan2
- MICAL1 | c.2658C>T p.D886= | Silent (SNP) | VAF 56/162 reads (35%) | called by muse, mutect2, varscan2
- MTUS2 | c.2013G>A p.P671= | Silent (SNP) | VAF 48/153 reads (31%) | catalogued as rs1424838911, COSV70916627; called by muse, mutect2, varscan2
- NUBP2 | c.405G>A p.P135= | Silent (SNP) | VAF 72/259 reads (28%) | catalogued as rs144072283; called by muse, mutect2, varscan2
- PCDH10 | c.915G>A p.P305= | Silent (SNP) | VAF 14/250 reads (6%) | catalogued as COSV52090642, COSV52096256; called by muse, mutect2
- PCDHA6 | c.1824G>A p.S608= | Silent (SNP) | VAF 151/512 reads (29%) | catalogued as rs782789312, COSV100971175, COSV65343226, COSV65345214; called by muse, mutect2, varscan2
- PCNX3 | c.1473G>A p.T491= | Silent (SNP) | VAF 106/356 reads (30%) | catalogued as rs887263138; called by muse, mutect2, varscan2
- QPCTL | c.1011C>T p.P337= | Silent (SNP) | VAF 47/142 reads (33%) | catalogued as rs777466140; called by muse, mutect2, varscan2
- SIMC1 | c.2553G>A p.L851= (on ENST00000443967 / NM_001308196.1; = p.L436= on NM_198567.5) | Silent (SNP) | VAF 21/204 reads (10%) | called by muse, mutect2
- SYCP2L | c.111T>C p.D37= | Silent (SNP) | VAF 45/164 reads (27%) | called by muse, mutect2, varscan2
- TUT7 | c.4299C>T p.L1433= | Silent (SNP) | VAF 16/458 reads (3%) | catalogued as rs930964561; called by muse, mutect2
- ZDHHC23 | c.786C>T p.A262= | Silent (SNP) | VAF 51/217 reads (24%) | called by muse, mutect2, varscan2
- ELK1 | c.-84G>A | 5'UTR (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- FAM27E5 | n.177C>T | RNA (SNP) | VAF 60/267 reads (22%) | catalogued as rs771362103; called by muse, mutect2, varscan2
- FAM71D | c.159+709A>C | Intron (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-46044G>A | Intron (SNP) | VAF 61/178 reads (34%) | called by muse, mutect2, varscan2
- MMAB | c.*790G>T | 3'UTR (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-110030C>T | Intron (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- RBMX2 | c.173+10C>A | Intron (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- STRA6 | c.597+20G>A | Intron (SNP) | VAF 107/370 reads (29%) | catalogued as rs1246268008; called by muse, mutect2, varscan2
- TMX2 | c.250+19T>G | Intron (SNP) | VAF 58/177 reads (33%) | called by muse, mutect2, varscan2
- YARS1 | c.58-35C>G | Intron (SNP) | VAF 76/295 reads (26%) | called by muse, mutect2, varscan2
